Somatic mutation profile of cancer-model specimen HCM-CSHL-0623-C18-85A (3D Organoid, passage 5; aliquot HCM-CSHL-0623-C18-85A-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0623-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.6 years (17,397 days).
Specimen HCM-CSHL-0623-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f97ee1d9-7a30-4908-bf5e-a0da0cd7c8ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0623-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0623-C18-11A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f96be6e-e27b-4b56-be37-acd13e4b9c8c

The open-access MAF lists 138 somatic variants for this specimen: 104 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 31, Splice Region 3, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 295/427 reads (69%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- ABCA2 | c.520A>G p.R174G (on ENST00000614293; = p.R144G on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/549 reads (6%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1463712149; called by muse, mutect2
- AHSG | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 135/433 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs1233480935; called by muse, mutect2, varscan2
- ARL6IP5 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 38/504 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.354); catalogued as rs747095530; called by muse, mutect2
- ASTN1 | c.2638C>T p.R880* | Nonsense Mutation (SNP) | VAF 109/229 reads (48%) | catalogued as rs267598195, COSV56067835, COSV99921068; called by muse, mutect2, varscan2
- BCL2L12 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 96/420 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs763853521, COSV99881409; called by muse, varscan2
- C1orf68 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 158/364 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs369426180, COSV64224874; called by muse, mutect2
- CARD9 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 136/442 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752685448; called by muse, varscan2
- CASP9 | c.417C>T p.V139= | Splice Region (SNP) | VAF 64/144 reads (44%) | catalogued as rs141693490; called by muse, mutect2, varscan2
- CATSPERD | c.1061C>A p.T354N | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1448152937, COSV58466208; called by muse, varscan2
- CELSR3 | c.5131G>A p.A1711T | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs758809338; called by muse, mutect2, varscan2
- COL11A1 | c.3286G>A p.G1096S | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV62172942; called by muse, mutect2
- CSRNP1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 282/422 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV56187051; called by muse, varscan2
- DCC | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1186332230, COSV59102884; called by muse, mutect2
- DCX | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV57568703; called by muse, mutect2, varscan2
- DDX60 | c.1749A>T p.R583S | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV67098253; called by muse, mutect2
- DPY19L2 | c.431T>C p.M144T | Missense Mutation (SNP) | VAF 116/179 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771726551, COSV60541674; called by muse, mutect2, varscan2
- DUS1L | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs539331883; called by muse, mutect2
- ENTPD4 | c.1286A>G p.Y429C | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775070986, COSV62268453; called by muse, mutect2, varscan2
- FGA | c.550T>G p.C184G | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM150544; called by muse, mutect2
- FLG | c.1384T>A p.S462T | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.983); catalogued as rs763220251; called by muse, mutect2
- FREM3 | c.5606T>C p.L1869P | Missense Mutation (SNP) | VAF 10/345 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1470345076; called by muse, mutect2
- GJA3 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 218/354 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs755792418, COSV99576226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOXD11 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 24/706 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1290778569; called by muse, mutect2
- IGSF21 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs141744591; called by muse, mutect2, varscan2
- KTN1 | c.1679G>T p.R560M | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1338037763; called by muse, mutect2
- LSM2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 22/541 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs951934346, COSV65151980; called by muse, mutect2
- MYH7 | c.5071G>A p.V1691M | Missense Mutation (SNP) | VAF 159/904 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs45464193, CM031282, COSV62518813, COSV62521627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCDN | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 28/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57844768; called by muse, mutect2
- NID1 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs763191195, COSV51614387; called by muse, varscan2
- NPR1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs762497355; called by muse, mutect2, varscan2
- OTOG | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs769988430; called by muse, varscan2
- PCDH15 | c.5035G>A p.G1679R (on ENST00000644397 / NM_001354429.2; = p.G1621R on NM_001142771.2) | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.52); catalogued as rs746744883; called by muse, mutect2
- PCLO | c.1489G>T p.A497S | Missense Mutation (SNP) | VAF 120/416 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV61614819; called by mutect2, varscan2
- PHTF2 | c.158A>C p.Y53S (on ENST00000248550 / NM_001366089.1; = p.Y19S on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/113 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99302135; called by muse, mutect2, varscan2
- PKD1 | c.4451C>T p.P1484L | Missense Mutation (SNP) | VAF 255/532 reads (48%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.845); catalogued as rs759853409, COSV99238788; called by muse, mutect2, varscan2
- RAPGEF6 | c.3874C>T p.R1292W | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs770850083; called by muse, mutect2, varscan2
- RFC4 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs781615742; called by muse, mutect2
- RIPPLY3 | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 86/172 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.412); catalogued as rs747701107, COSV61567006; called by muse, mutect2, varscan2
- ROBO2 | c.3383G>A p.R1128K | Missense Mutation (SNP) | VAF 33/346 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV59950979; called by muse, varscan2
- ROBO2 | c.3384G>T p.R1128S | Missense Mutation (SNP) | VAF 33/348 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.815); catalogued as rs202001765; called by muse, varscan2
- RTEL1 | c.3345G>A p.R1115= | Splice Region (SNP) | VAF 76/681 reads (11%) | catalogued as rs752407024; called by muse, mutect2, varscan2
- SERPINC1 | c.1358T>C p.I453T | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM940137; called by muse, mutect2
- SHCBP1L | c.1462A>G p.I488V | Missense Mutation (SNP) | VAF 128/286 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs778662886; called by muse, mutect2, varscan2
- SLITRK2 | c.1112A>T p.Q371L | Missense Mutation (SNP) | VAF 11/378 reads (3%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as COSV59425589; called by muse, mutect2
- STK11 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 19/622 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs1060499954, COSV58825041; ClinVar: uncertain significance; called by muse, mutect2
- TRMT10C | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.124); catalogued as rs1256495203; called by muse, mutect2, varscan2
- TTN | c.54376G>C p.D18126H (on ENST00000591111; = p.D10702H on NM_003319.4) | Missense Mutation (SNP) | VAF 32/420 reads (8%) | PolyPhen possibly damaging (0.772); catalogued as COSV60039931; called by muse, mutect2
- USP26 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 264/264 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275240166, COSV100896789; called by muse, mutect2, varscan2
- ACOX2 | c.1136A>T p.D379V | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ADGRB3 | c.1524T>A p.P508= | Splice Region (SNP) | VAF 15/156 reads (10%) | called by muse, mutect2
- ANKRD36C | c.4574G>T p.R1525I | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2
- AP002748.5 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP24 | c.1950C>A p.S650R (on ENST00000395184 / NM_001025616.3; = p.S557R on NM_031305.3) | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2
- CCDC121 | c.551C>A p.A184E | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CCDC3 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.203); called by muse, mutect2
- CD320 | c.29G>C p.G10A | Missense Mutation (SNP) | VAF 38/674 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.47); called by muse, mutect2
- CYLC2 | c.1044G>C p.K348N | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- DAG1 | c.1147G>T p.G383C | Missense Mutation (SNP) | VAF 30/530 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- DAG1 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 30/531 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- DLGAP4 | c.2174G>T p.S725I (on ENST00000339266 / NM_001365621.1; = p.S722I on NM_014902.6) | Missense Mutation (SNP) | VAF 56/1156 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); called by muse, mutect2
- DQX1 | c.1756C>A p.Q586K | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- EEF1A1 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 232/304 reads (76%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ERICH3 | c.2768G>T p.R923I | Missense Mutation (SNP) | VAF 19/416 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2
- ERN2 | c.780G>T p.W260C | Missense Mutation (SNP) | VAF 29/748 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.135); called by muse, mutect2
- FAM71B | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- FBN1 | c.6404A>G p.D2135G | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); called by muse, mutect2
- GABRB1 | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLI3 | c.3176A>C p.N1059T | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.024); called by muse, mutect2
- HCN1 | c.1714G>T p.V572F | Missense Mutation (SNP) | VAF 20/548 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HMGB3 | c.443A>T p.K148M | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- KASH5 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 54/602 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- KIAA1522 | c.2447G>C p.G816A (on ENST00000373480 / NM_001198972.2; = p.G875A on NM_020888.3) | Missense Mutation (SNP) | VAF 23/466 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2
- MACF1 | c.4078T>A p.F1360I | Missense Mutation (SNP) | VAF 116/229 reads (51%) | called by muse, mutect2, varscan2
- MALRD1 | c.596A>T p.Q199L | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2
- MAP3K9 | c.481G>C p.A161P | Missense Mutation (SNP) | VAF 47/685 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MAPRE1 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 24/572 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- MXRA5 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 17/370 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2
- NR0B1 | c.17A>G p.H6R | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.478); called by mutect2, varscan2
- NTRK1 | c.1399C>A p.H467N | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PHF3 | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- PPP1R36 | c.767dup p.L256Ffs*5 | Frame Shift Ins (INS) | VAF 120/342 reads (35%) | called by mutect2, varscan2
- RABL6 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RBL1 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RFX5 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.038); called by muse, mutect2
- RNF126 | c.915G>C p.E305D | Missense Mutation (SNP) | VAF 41/417 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ROBO2 | c.3382A>T p.R1128W | Missense Mutation (SNP) | VAF 33/349 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- SEMG1 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 399/698 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, varscan2
- SEZ6L | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2
- SLC14A2 | c.2245C>A p.P749T | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- SLC4A10 | c.790T>G p.S264A | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- SPTBN5 | c.8079G>C p.E2693D | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- SRFBP1 | c.792C>A p.S264R | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TOB1 | c.797C>A p.A266D | Missense Mutation (SNP) | VAF 23/426 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- TOM1L2 | c.466T>G p.L156V (on ENST00000379504 / NM_001350333.2; = p.L106V on NM_001033551.3) | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2
- TSPYL6 | c.304T>A p.S102T | Missense Mutation (SNP) | VAF 36/588 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.227); called by muse, mutect2
- UBR1 | c.3266C>G p.S1089C | Missense Mutation (SNP) | VAF 8/237 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.219); called by muse, mutect2
- UBR3 | c.5160G>C p.E1720D | Missense Mutation (SNP) | VAF 10/314 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); called by muse, mutect2
- UPF3A | c.935A>T p.Q312L | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.057); called by muse, mutect2
- VEZF1 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 28/405 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- VTN | c.232T>A p.Y78N | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2
- WASF3 | c.1202C>A p.P401Q | Missense Mutation (SNP) | VAF 273/494 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ZER1 | c.767A>T p.D256V | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); called by muse, mutect2
- ZNF781 | c.650T>A p.L217H | Missense Mutation (SNP) | VAF 96/285 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ACTL8 | c.30C>T p.H10= | Silent (SNP) | VAF 123/250 reads (49%) | catalogued as rs760974264; called by muse, mutect2, varscan2
- ASPDH | c.210G>T p.L70= (on ENST00000389208 / NM_001114598.2; = p.L15= on NM_001024656.3) | Silent (SNP) | VAF 115/302 reads (38%) | called by muse, mutect2, varscan2
- BNIP5 | c.156C>T p.T52= | Silent (SNP) | VAF 34/684 reads (5%) | called by muse, mutect2
- C2CD4B | c.366G>A p.A122= | Silent (SNP) | VAF 197/365 reads (54%) | called by muse, mutect2, varscan2
- CLEC9A | c.483T>A p.T161= | Silent (SNP) | VAF 140/224 reads (63%) | called by muse, mutect2, varscan2
- DNHD1 | c.3612C>A p.G1204= | Silent (SNP) | VAF 18/316 reads (6%) | catalogued as rs376064043; called by muse, mutect2
- DTNA | c.2148G>A p.R716= | Silent (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- ELFN1 | c.2352C>G p.R784= | Silent (SNP) | VAF 119/430 reads (28%) | called by muse, mutect2, varscan2
- EN1 | c.441C>A p.G147= | Silent (SNP) | VAF 66/803 reads (8%) | called by muse, mutect2
- FOXC2 | c.709C>T p.L237= | Silent (SNP) | VAF 42/1060 reads (4%) | catalogued as rs1172772863; called by muse, mutect2
- GRIA2 | c.804G>A p.S268= | Silent (SNP) | VAF 60/245 reads (24%) | catalogued as rs199736067; ClinVar: likely benign; called by muse, mutect2, varscan2
- GSPT2 | c.1572T>C p.V524= | Silent (SNP) | VAF 36/318 reads (11%) | catalogued as COSV61214109; called by muse, mutect2, varscan2
- GUCY1A1 | c.1659C>A p.A553= | Silent (SNP) | VAF 14/420 reads (3%) | called by muse, mutect2
- HSPG2 | c.11505C>G p.L3835= | Silent (SNP) | VAF 55/297 reads (19%) | catalogued as COSV65933568; called by muse, mutect2, varscan2
- IL36RN | c.351G>A p.P117= | Silent (SNP) | VAF 154/468 reads (33%) | catalogued as rs202161658; called by muse, mutect2, varscan2
- MGAT3 | c.360C>T p.P120= | Silent (SNP) | VAF 30/450 reads (7%) | catalogued as rs372097244; called by muse, mutect2
- MRM2 | c.168C>T p.S56= | Silent (SNP) | VAF 372/551 reads (68%) | catalogued as rs145102163, COSV54248553; called by muse, mutect2, varscan2
- MXRA5 | c.1056T>A p.P352= | Silent (SNP) | VAF 16/375 reads (4%) | called by muse, mutect2
- NID1 | c.2553C>T p.H851= | Silent (SNP) | VAF 177/351 reads (50%) | catalogued as rs765999192, COSV51627966; called by muse, mutect2, varscan2
- PABPC4L | c.240C>T p.S80= | Silent (SNP) | VAF 20/380 reads (5%) | catalogued as COSV69929546; called by muse, mutect2
- PGPEP1L | c.45G>T p.G15= | Silent (SNP) | VAF 62/148 reads (42%) | called by muse, mutect2, varscan2
- PIK3C2G | c.3087A>G p.P1029= (on ENST00000676171; = p.P988= on NM_004570.5) | Silent (SNP) | VAF 86/312 reads (28%) | called by muse, mutect2, varscan2
- PRDM14 | c.1230C>A p.T410= | Silent (SNP) | VAF 16/372 reads (4%) | called by muse, mutect2
- RHBG | c.49C>T p.L17= | Silent (SNP) | VAF 12/401 reads (3%) | called by muse, mutect2
- RPTOR | c.2604C>T p.G868= | Silent (SNP) | VAF 181/458 reads (40%) | catalogued as rs748388080; called by muse, mutect2, varscan2
- TLR7 | c.2962T>C p.L988= | Silent (SNP) | VAF 142/282 reads (50%) | called by muse, varscan2
- TMEM198 | c.936C>A p.V312= | Silent (SNP) | VAF 161/274 reads (59%) | called by muse, varscan2
- TNIP3 | c.810C>T p.C270= | Silent (SNP) | VAF 86/310 reads (28%) | catalogued as rs370272164; called by muse, mutect2, varscan2
- UPF3A | c.936G>A p.Q312= | Silent (SNP) | VAF 28/360 reads (8%) | catalogued as rs1047954925; called by muse, mutect2
- ZBTB18 | c.360A>G p.K120= | Silent (SNP) | VAF 108/267 reads (40%) | called by muse, mutect2, varscan2
- ZNF541 | c.162G>A p.P54= | Silent (SNP) | VAF 163/499 reads (33%) | catalogued as rs568955111, COSV100026730; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823002 C>G | 5'Flank (SNP) | VAF 7/191 reads (4%) | called by muse, mutect2
- OSGIN1 | n.406G>T | RNA (SNP) | VAF 16/516 reads (3%) | catalogued as rs1409483428; called by muse, mutect2
- TTN | c.10361-4992C>T | Intron (SNP) | VAF 211/333 reads (63%) | catalogued as rs727504760, COSV60134899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
